Somatic mutation profile of tumor specimen TCGA-DK-A1AA-01A (aliquot TCGA-DK-A1AA-01A-11D-A13W-08) from TCGA case TCGA-DK-A1AA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 57.7 years (21,093 days).
Specimen TCGA-DK-A1AA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aa9cbde-b8db-4959-898a-e93dbf8cc466.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1AA-10A (Blood Derived Normal), aliquot TCGA-DK-A1AA-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a654266-eb47-46de-ab9c-63132f9b8704

The open-access MAF lists 88 somatic variants for this specimen: 70 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 15, Nonsense Mutation 5, Frame Shift Ins 3, 5'UTR 1, Intron 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 98/250 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 22/24 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AATK | c.2554G>A p.E852K (on ENST00000326724 / NM_001080395.3; = p.E749K on NM_004920.2) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as rs375510759; called by muse, mutect2
- ABCB5 | c.2408C>G p.A803G (on ENST00000404938 / NM_001163941.2; = p.A358G on NM_178559.6) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV51716080; called by muse, mutect2, varscan2
- ABCG4 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100266644, COSV56644989, COSV56645081; called by muse, mutect2, varscan2
- ADRA1A | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52370074; called by muse, mutect2, varscan2
- ATAD2B | c.3937C>G p.Q1313E | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV53203014; called by muse, mutect2, varscan2
- BCHE | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52259904; called by muse, mutect2, varscan2
- BCL9 | c.2516G>T p.R839L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV52344790, COSV52347993; called by muse, mutect2, varscan2
- CACNA1D | c.1558G>T p.V520L (on ENST00000350061 / NM_001128840.3; = p.V540L on NM_000720.4) | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV55457540, COSV55459377; called by muse, mutect2, varscan2
- CACNA1D | c.5542A>G p.S1848G (on ENST00000350061 / NM_001128840.3; = p.S1868G on NM_000720.4) | Missense Mutation (SNP) | VAF 139/279 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55457553; called by muse, mutect2, varscan2
- CADPS | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.089); catalogued as rs1022980072, COSV51892970, COSV99336586; called by muse, mutect2, varscan2
- CARD14 | c.1243A>G p.K415E | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60125365; called by muse, mutect2, varscan2
- CCDC74A | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as rs1264963868; called by muse, mutect2, varscan2
- CDH13 | c.996G>C p.E332D | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV51849421; called by muse, mutect2, varscan2
- CRACD | c.2771C>A p.S924Y | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV51727186; called by muse, mutect2, varscan2
- DGKB | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1199827628, COSV51805011; called by muse, mutect2, varscan2
- EHD4 | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV55006179; called by muse, mutect2, varscan2
- FILIP1 | c.2078C>A p.A693E | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV52736340; called by muse, mutect2, varscan2
- FREM2 | c.6061G>A p.E2021K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1282183231, COSV54845381; called by muse, mutect2, varscan2
- GAREM1 | c.1100A>T p.H367L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV52513266, COSV52517045; called by muse, mutect2, varscan2
- GPM6A | c.71del p.G24Afs*7 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | catalogued as COSV54541068; called by mutect2, pindel, varscan2
- HNRNPA1 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV52937972; called by muse, mutect2, varscan2
- HOXA2 | c.998G>A p.C333Y | Missense Mutation (SNP) | VAF 105/216 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV56067260; called by muse, mutect2, varscan2
- HRG | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51646882; called by muse, mutect2, varscan2
- IL7 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.424); catalogued as COSV55676770; called by muse, mutect2, varscan2
- ITPR3 | c.2701A>T p.M901L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV65412716; called by muse, mutect2, varscan2
- LCE3D | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.649); catalogued as rs147417899; called by muse, mutect2, varscan2
- LMCD1 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.127); catalogued as COSV50089895; called by muse, mutect2, varscan2
- LMF2 | c.1475G>C p.R492P | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV53317163, COSV53318405; called by muse, mutect2, varscan2
- MORC1 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV51726235, COSV51730923; called by muse, mutect2, varscan2
- MUC16 | c.24106G>A p.E8036K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV67480952; called by muse, mutect2, varscan2
- MUC16 | c.16961C>A p.P5654H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.815); catalogued as rs1167161835, COSV67451526; called by muse, mutect2, varscan2
- MYH7 | c.1631C>T p.T544I | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV62521777; called by muse, mutect2, varscan2
- MYSM1 | c.279T>A p.D93E | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV68977994; called by muse, mutect2, varscan2
- NETO2 | c.227T>C p.L76S | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57454638; called by muse, mutect2, varscan2
- NUP210L | c.4114G>T p.G1372W | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55153465; called by muse, mutect2
- OR4P4 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58923044; called by muse, mutect2, varscan2
- PCDHB9 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as rs369161237, COSV53381612; called by muse, mutect2, varscan2
- PCDHGA12 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52760322; called by muse, mutect2, varscan2
- PDGFRA | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.7); PolyPhen probably damaging (1); catalogued as COSV57266225, COSV57271287; called by muse, mutect2, varscan2
- PIP5K1C | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58954414; called by muse, mutect2, varscan2
- PLEK | c.245A>G p.Q82R | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52253098; called by muse, mutect2, varscan2
- PRAMEF10 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1218511457; called by muse, mutect2, varscan2
- PRKG2 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs187350442; called by muse, mutect2, varscan2
- RAD18 | c.206A>G p.E69G | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV53751860; called by muse, mutect2, varscan2
- RYR2 | c.12427A>G p.K4143E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs750908017, COSV63701409; called by muse, mutect2, varscan2
- SEC23IP | c.2285A>T p.Y762F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as COSV64832407; called by muse, mutect2, varscan2
- SF3B3 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56787109; called by muse, mutect2, varscan2
- SLC44A4 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.098); catalogued as rs1264379730, COSV57668452; called by muse, mutect2, varscan2
- SLC9C2 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs201611790, COSV62944546; called by muse, mutect2, varscan2
- SPTAN1 | c.4971_4972insT p.N1658* | Frame Shift Ins (INS) | VAF 66/101 reads (65%) | catalogued as COSV63988814; called by mutect2, pindel, varscan2
- SUPT5H | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV63241090; called by muse, mutect2, varscan2
- SYNE1 | c.14703G>T p.R4901S (on ENST00000367255 / NM_182961.4; = p.R4830S on NM_033071.3) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV55047496, COSV99564360; called by muse, mutect2, varscan2
- TMC2 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.221); catalogued as COSV62656279; called by muse, mutect2, varscan2
- TPO | c.2240G>A p.S747N | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs750689640, COSV61107001; called by muse, mutect2
- TRHR | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as COSV61235681; called by muse, mutect2, varscan2
- TSC2 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV54784171; called by muse, mutect2, varscan2
- TSHZ3 | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53671157, COSV53677676; called by muse, mutect2, varscan2
- TTC37 | c.1708C>T p.R570* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as rs768215813, CM130215; called by muse, mutect2, varscan2
- TTN | c.90292G>A p.E30098K (on ENST00000591111; = p.E22674K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | PolyPhen benign (0.022); catalogued as COSV100596648, COSV60170730; called by muse, mutect2, varscan2
- TTN | c.1550C>T p.T517I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | PolyPhen probably damaging (0.991); catalogued as rs370026046; called by muse, mutect2, varscan2
- UTRN | c.3070G>A p.D1024N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs370435884; called by muse, mutect2, varscan2
- WDR11 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54790920; called by muse, mutect2, varscan2
- ZBTB46 | c.267C>G p.F89L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55512746; called by muse, mutect2, varscan2
- IRF6 | c.102dup p.R35Tfs*13 | Frame Shift Ins (INS) | VAF 68/194 reads (35%) | called by mutect2, pindel, varscan2
- KDM6A | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 58/68 reads (85%) | called by muse, mutect2, varscan2
- STAC3 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- STAG2 | c.2748dup p.K917* | Frame Shift Ins (INS) | VAF 41/62 reads (66%) | called by mutect2, pindel, varscan2
- UTY | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 25/27 reads (93%) | called by muse, mutect2, varscan2
- C7orf25 | c.21C>T p.L7= | Silent (SNP) | VAF 155/340 reads (46%) | catalogued as rs113806989, COSV63274039; called by muse, mutect2, varscan2
- CCNA2 | c.1044C>G p.L348= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV54667186; called by muse, mutect2, varscan2
- CEP164 | c.1695C>T p.V565= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV54044162; called by muse, mutect2, varscan2
- DCAF15 | c.1497C>T p.F499= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV54332090; called by muse, mutect2, varscan2
- FAM53A | c.705C>T p.P235= | Silent (SNP) | VAF 12/12 reads (100%) | catalogued as COSV57402539; called by muse, mutect2, varscan2
- FBLN7 | c.1026C>A p.L342= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as COSV55616872; called by muse, mutect2, varscan2
- KIR3DL2 | c.1015C>T p.L339= | Silent (SNP) | VAF 47/112 reads (42%) | catalogued as COSV54394077; called by muse, mutect2, varscan2
- KIRREL1 | c.2103C>T p.Y701= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1212510271, COSV63289836; called by muse, mutect2, varscan2
- NR2C1 | c.1203G>T p.L401= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV58011413; called by muse, mutect2, varscan2
- PKHD1 | c.11547G>A p.L3849= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- PKHD1 | c.11545T>C p.L3849= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV64396034; called by muse, mutect2
- PNMA2 | c.1089C>T p.D363= | Silent (SNP) | VAF 81/185 reads (44%) | catalogued as rs202002019; called by muse, mutect2, varscan2
- TNXB | c.8820G>A p.K2940= (on ENST00000647633; = p.K2693= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs749439259, COSV64484274; called by muse, mutect2, varscan2
- TRPS1 | c.2517G>T p.A839= (on ENST00000220888 / NM_001330599.2; = p.A852= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV55253594, COSV55265582; called by muse, mutect2, varscan2
- XPO6 | c.3195C>T p.F1065= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV58969271; called by muse, mutect2, varscan2
- GKN1 | c.-36dup | 5'UTR (INS) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- KLRA1P | n.332G>A | RNA (SNP) | VAF 8/17 reads (47%) | catalogued as rs758314007; called by muse, mutect2, varscan2
- TTN | c.10360+5453T>C | Intron (SNP) | VAF 9/32 reads (28%) | catalogued as COSV60219449; called by muse, mutect2, varscan2
